Somatic mutation profile of tumor specimen TCGA-A5-A0GJ-01A (aliquot TCGA-A5-A0GJ-01A-11W-A062-09) from TCGA case TCGA-A5-A0GJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 45.0 years (16,421 days).
Specimen TCGA-A5-A0GJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a077cb7c-066b-4cc2-9253-56fe68857fb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0GJ-10A (Blood Derived Normal), aliquot TCGA-A5-A0GJ-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6799dc25-cb92-4943-a7a0-b8b38d5a2c79

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Nonsense Mutation 4, Splice Site 3, Frame Shift Del 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD6 | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1419107305, COSV61086251; called by muse, mutect2, varscan2
- FRMD6 | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV61086258; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 22/36 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD17B | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.133); catalogued as COSV61006871; called by muse, mutect2, varscan2
- ACSM5 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1263030856, COSV59369242; called by muse, mutect2, varscan2
- ADAMTS19 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50731276; called by muse, mutect2, varscan2
- AHNAK2 | c.2923C>G p.L975V | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV60906383; called by muse, mutect2, varscan2
- ALG8 | c.1515T>G p.Y505* | Nonsense Mutation (SNP) | VAF 51/169 reads (30%) | catalogued as COSV55199049; called by muse, mutect2, varscan2
- ANAPC1 | c.1456G>C p.D486H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61973963; called by muse, mutect2, varscan2
- ARHGAP20 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs779631650, COSV52805862; called by muse, mutect2, varscan2
- ARHGAP20 | c.1313T>G p.L438R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52805874; called by muse, mutect2, varscan2
- CCDC148 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.628); catalogued as COSV51753189; called by muse, mutect2, varscan2
- CCNE2 | c.898G>T p.A300S | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57374836; called by muse, mutect2, varscan2
- CD163 | c.1840A>G p.I614V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV63128978; called by muse, mutect2, varscan2
- CDH10 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373340564, COSV52576463; called by muse, mutect2, varscan2
- CFAP47 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as COSV52880018; called by muse, mutect2, varscan2
- COL4A4 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as COSV61629192; called by muse, mutect2, varscan2
- DNMBP | c.3124C>T p.R1042* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as rs1341019017, COSV100143499, COSV60619695; called by muse, mutect2, varscan2
- DPRX | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64949146; called by muse, mutect2, varscan2
- EP400 | c.3325G>C p.V1109L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57761400; called by muse, mutect2, varscan2
- FAM71B | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV57227297; called by muse, mutect2, varscan2
- FAM71F1 | c.722G>C p.S241T | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV59372677; called by muse, mutect2, varscan2
- FBN2 | c.1340A>T p.N447I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.445); catalogued as COSV52489689, COSV52539500; called by muse, mutect2, varscan2
- GARS1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as rs767696937, COSV66827720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HPR | c.829A>C p.N277H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57181340; called by muse, mutect2, varscan2
- HRNR | c.5149C>T p.R1717* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as rs1263607205; called by mutect2, varscan2
- KBTBD3 | c.536A>T p.H179L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV73241185; called by muse, mutect2, varscan2
- LRP1B | c.2577A>T p.Q859H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63341545, COSV63341769; called by muse, mutect2, varscan2
- MAOB | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV65204097; called by muse, mutect2, varscan2
- MAP3K5 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV62886508; called by muse, mutect2, varscan2
- MCF2 | c.1764del p.Y588* | Frame Shift Del (DEL) | VAF 123/231 reads (53%) | catalogued as COSV58476808; called by mutect2, pindel, varscan2
- MITF | c.1310G>T p.C437F (on ENST00000448226 / NM_006722.3; = p.C337F on NM_000248.4) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.219); catalogued as rs760057624, COSV58829435; called by muse, mutect2, varscan2
- MMP12 | c.460A>T p.T154S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58258891; called by muse, mutect2, varscan2
- MMRN1 | c.1354A>T p.T452S | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV53333270; called by muse, mutect2, varscan2
- MS4A6A | c.118C>T p.H40Y | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60616253; called by muse, mutect2, varscan2
- NCAM2 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53053575; called by muse, mutect2, varscan2
- NELL2 | c.2291C>G p.T764S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.079); catalogued as COSV61567989; called by muse, mutect2, varscan2
- NLRC4 | c.2269G>C p.D757H | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV61590929; called by muse, mutect2, varscan2
- NTF3 | c.140A>C p.K47T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV58417078; called by muse, mutect2, varscan2
- NUMB | c.1769A>G p.N590S (on ENST00000355058; = p.N579S on NM_003744.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs549478016, COSV53712453; called by muse, mutect2, varscan2
- OR2T33 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 55/320 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV58813609; called by muse, mutect2, varscan2
- PCDHAC1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs370145398; called by muse, mutect2, varscan2
- PCDHAC1 | c.1654T>G p.Y552D | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53835824; called by muse, mutect2, varscan2
- PCDHGA4 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs749145164, COSV53891978; called by muse, mutect2, varscan2
- PDILT | c.88A>G p.S30G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56699188; called by muse, mutect2, varscan2
- PRR14 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV54910601; called by muse, mutect2, varscan2
- PRSS35 | c.283T>A p.L95I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as COSV63800021; called by muse, mutect2, varscan2
- RIMKLA | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.391); catalogued as COSV68909644, COSV68909788; called by muse, mutect2
- RIN3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs770646852, COSV53644431, COSV53644790; called by muse, mutect2, varscan2
- RNF14 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.034); catalogued as COSV61662029; called by muse, mutect2, varscan2
- SCAI | c.1229A>C p.H410P (on ENST00000336505 / NM_001144877.3; = p.H433P on NM_173690.5) | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as rs1475450869, COSV60609490; called by muse, mutect2, varscan2
- SCML2 | c.1457-2A>T p.X486_splice | Splice Site (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52617981; called by muse, mutect2, varscan2
- SRPRA | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55004917; called by muse, mutect2, varscan2
- STAB2 | c.4615G>C p.A1539P | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV66333467; called by muse, mutect2, varscan2
- SYT16 | c.956C>G p.S319C | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV70854744, COSV70856800; called by muse, mutect2, varscan2
- TNKS2 | c.558-1G>C p.X186_splice | Splice Site (SNP) | VAF 20/33 reads (61%) | catalogued as COSV65414520; called by muse, mutect2
- TRIM71 | c.1743G>T p.K581N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV67469970; called by muse, mutect2, varscan2
- TSC22D1 | c.2944A>G p.N982D (on ENST00000458659 / NM_183422.4; = p.N53D on NM_006022.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV54925287; called by muse, mutect2, varscan2
- UBR4 | c.3401C>G p.S1134C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as COSV64382051; called by muse, mutect2, varscan2
- VWA8 | c.2393T>C p.L798P | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55691346; called by muse, mutect2, varscan2
- ZNF620 | c.1174T>C p.Y392H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV58820002; called by muse, mutect2, varscan2
- GUCA1A | c.393_432del p.A132Sfs*13 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel
- ITPR3 | c.1537A>G p.N513D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2
- SSR1 | c.700-19_714del p.X234_splice | Splice Site (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- ANKRD12 | c.1242A>G p.K414= | Silent (SNP) | VAF 70/207 reads (34%) | catalogued as COSV50818986; called by muse, mutect2, varscan2
- C16orf72 | c.747T>C p.G249= | Silent (SNP) | VAF 81/198 reads (41%) | catalogued as COSV59915538; called by muse, mutect2, varscan2
- CAMTA1 | c.1872C>A p.P624= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as COSV57879320; called by muse, mutect2, varscan2
- CECR2 | c.2010C>T p.S670= (on ENST00000342247 / NM_001290047.2; = p.S487= on NM_001290046.1) | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV52835267; called by muse, mutect2, varscan2
- CERS3 | c.543C>T p.Y181= | Silent (SNP) | VAF 27/44 reads (61%) | catalogued as COSV52564296; called by muse, mutect2, varscan2
- CES5A | c.372G>A p.L124= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as rs149280225; called by muse, mutect2, varscan2
- ESR2 | c.783C>T p.D261= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs750886730, COSV50828395; called by muse, mutect2, varscan2
- GEM | c.312C>T p.S104= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs758312817, COSV52596527; called by muse, mutect2, varscan2
- IL22 | c.192C>T p.S64= | Silent (SNP) | VAF 31/82 reads (38%) | catalogued as rs768540263, COSV60159662; called by muse, mutect2, varscan2
- MYH4 | c.4248T>G p.A1416= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as rs1405425196, COSV55111234; called by muse, mutect2, varscan2
- NUTM2G | c.105C>T p.P35= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs548799786, COSV63616801; called by muse, mutect2, varscan2
- NXPH2 | c.192G>A p.P64= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs776374165, COSV55639337; called by muse, mutect2, varscan2
- PDE1C | c.333G>A p.T111= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs1258531376, COSV58501921; called by muse, mutect2, varscan2
- RYR2 | c.10845G>A p.R3615= | Silent (SNP) | VAF 27/46 reads (59%) | catalogued as COSV100770817, COSV63657328; called by muse, mutect2, varscan2
- SREBF2 | c.411C>T p.P137= | Silent (SNP) | VAF 36/57 reads (63%) | catalogued as COSV63330305; called by muse, mutect2, varscan2
- TNXB | c.3979C>T p.L1327= (on ENST00000647633; = p.L1080= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1392228352, COSV64472456; called by muse, mutect2, varscan2
- ZSCAN31 | c.483G>C p.V161= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV60180141; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824018 T>A | 5'Flank (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2
- OR3A4P | n.1054G>A | RNA (SNP) | VAF 50/69 reads (72%) | catalogued as rs779114406; called by muse, mutect2, varscan2
